Surgical pathology report (de-identified scan), TCGA case TCGA-FU-A770, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FU-A770-01A (Primary Tumor).

[page 1 of 2]
Sex: Female
D.O.B.:
MRN #:
Ref Physician:

SPECIMEN INFORMATION

Collected:
Received:
Reported:

Accession #:
Acct / Reg #:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. left pelvic lymph nodes, excision:
5 lymph nodes, negative for metastatic disease.
Frozen section diagnosis confirmed.

B. right pelvic lymph nodes, excision:
1 of 5 lymph nodes positive for metastatic carcinoma.
Frozen section discordance due to sampling.

C. uterine artery, biopsy:
Negative for malignancy.

D. uterus with bilateral adnexa, hysterectomy with bilateral salpingo-oophorectomy:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Histologic grade: 2, moderately differentiated.
3. Tumor site: Cervix with extension into lower uterine segment.
4. Tumor size: 4.5 x 2.5 cm.
5. Stromal invasion/depth/horizontal extent: Tumor extends 1.0 CM into a 1.3 CM thick cervical/lower uterine segment wall.
6. Lymphovascular space invasion: Not identified.

Surgical Margin Status:

1. Vaginal margin: Negative.
2. Deep margin: Negative.

Lymph Node Status:

1. Total number of lymph nodes received: 10.
2. Total number of lymph nodes containing metastatic carcinoma: 1.

Other:

1. Other significant findings: Benign proliferative endometrium, bilateral ovaries and fallopian tubes without significant abnormality.
2. pTNM stage: pT2a2N1 (FIGO IIIB).

Comment:

Appropriately controlled immunohistochemical stains for p16 and WT1 performed on blocks B2 and D2 show tumor foci are positive for p16 and negative for WT1. These findings are consistent with metastatic endocervical adenocarcinoma.

ICD-O-3
Adenocarcinoma, endocervical
Type 884/3
Site Cervix NOS
C53.9
JW 8/19/13

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: History of cervical cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Left pelvic lymph node FS
- B. Right pelvic lymph node FS
- C. Uterine artery
- D. Uterus, cervix and bilateral tubes and ovaries

SPECIMEN DATA

GROSS DESCRIPTION:

A. Received label

1 #1 left pelvic lymph node is a 6.1 x 4.5 x 4.7 cm aggregate of fibroadipose tissue bearing the following:

[page 2 of 2]
REGIMEN INFORMATION

yellow firm tissues consistent with probable lymph nodes ranging from 1.1 x 0.4 x 0.2 cm to 4.5 x 2.2 x 0.3 cm. The specimen is sectioned and one lymph node is bisected and submitted in its entirety for frozen section and the frozen section residue is submitted in block 1. Additional representative sections are submitted to include the lymph nodes in their entirety as labeled: block 2—three whole possible lymph nodes; blocks 3-6—one lymph node, serially sectioned. The blocks are labeled

B. Received labeled and #2 right pelvic lymph node is a 4.9 x 3.5 x 0.6 cm aggregate of fibroadipose tissue bearing five irregular tan-yellow firm tissues consistent with probable lymph nodes ranging from 0.6 x 0.4 x 0.2 cm to 2.8 x 0.7 x 0.3 cm. The specimen is sectioned, a lymph node is bisected and submitted in its entirety for frozen section and the frozen section residue is submitted in blocks 1 and 2. Additional representative sections are submitted to include the lymph nodes in their entirety as labeled: block 3—one whole probable lymph node; blocks 4-6—one lymph node, bisected in each. The blocks are labeled

C. Received in form and #3 uterine artery is a 0.5 x 0.3 x 0.2 cm irregular tan-yellow soft tissue which is submitted in toto in one cassette labeled

D. Received labeled and #4 uterus, cervix and bilateral tubes and ovaries is a 121 gram hysterectomy specimen consisting of a 6.2 x 4.3 x 2.4 cm uterine body and an attached 3.3 x 3.0 x 2.6 cm cervix.

The serosa is smooth and tan-pink. The ectocervix is smooth and gray-white with a 1.8 x 1.7 cm bosselated friable tan-red lesion. The ectocervix is surrounded by a rim of gray-white vaginal mucosa. The endocervical canal consists of a 4.5 x 2.5 cm gray-white to tan-red mass, diffusely involving the cervix. The lesion extends into the lower uterine segment. The cut surface of the lesion is gray-white and is 0.4 cm from the deep margin. The lesion at the lower uterine segment has a glistening gray-white cut surface and averages 1.3 cm in thickness. The lesion is 0.3 cm from the serosa.

The endometrial cavity is 1.2 cm from cornu to cornu and 3.1 cm in length. The endometrium is glistening tan-pink, lush, and averages 0.3 cm in thickness. No endometrial lesions are identified. The myometrium is trabeculated tan-pink and averages 1.5 cm in thickness. No myometrial nodules are identified.

No lesions or lymph nodes are identified in the left and right paracervical soft tissue.

Also received in the same container is a 2.3 x 2.0 x 0.7 cm ovary with an attached 3.9 x 0.4 cm fimbriated fallopian tube. The outer surface of the ovary is lobulated and tan-purple. The cut surface is tan-pink with gray-white corpora albicans orange lined corpora luteal cysts and multiple smooth lined serous fluid filled cysts ranging from 0.4 cm to 0.9 cm in greatest dimension. The fallopian tube has a tan-pink serosa and a pinpoint lumen.

There is also a 2.8 x 2.0 x 1.3 cm ovary with an attached 4.8 x 0.5 cm fimbriated fallopian tube. The outer surface of the ovary is smooth to lobulated and tan-pink. The cut surface is tan-pink with gray-white corpora albicans orange lined corpora luteal cysts and multiple smooth lined serous fluid filled cysts ranging from 0.5 cm to 1.3 cm in greatest dimension. The fallopian tube has a tan-red serosa and multiple paratubal cysts ranging from 0.1 cm to 0.7 cm in greatest dimension and a pinpoint lumen.

The specimen is inked, serially sectioned and representative sections are submitted as labeled: block 1—cervix 12 to 3:00; block 2—cervix 3 to 6:00; block 3—cervix 6 to 9:00; block 4—cervix 9 to 12:00; block 5—anterior lower uterine segment; block 6—posterior lower uterine segment; block 7—anterior endomyometrium with serosa; block 8—posterior endomyometrium with serosa; block 9—left paracervical soft tissue; block 10—right paracervical soft tissue; blocks 11 and 12—smaller ovary and attached fallopian tube; blocks 13 and 14—larger ovary and attached fallopian tube. The blocks are labeled

Also received in the same container is a green, yellow and blue cassette labeled

PERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSES A&B: Representative lymph node is negative for malignancy

Dual/Synchronous Tumor		✓
Case is Note	QUALIFIED	QUALIFIED

Source: NCI Genomic Data Commons file fe4afa8d-13cf-4bc9-9e73-19ea7312dcdb (TCGA-FU-A770.23DD976D-0D35-4BFF-89FF-94D9160F2228.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).